Gene-level copy-number profile of tumor specimen CUPP-B45H-TTM1-A from CCG case CUPP-B45H, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, metastatic; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 65.0 years (23,746 days).
Specimen CUPP-B45H-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ade83620-111c-41e0-84c9-49b40e9aa1cc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B45H-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,731 have no estimate.
https://portal.gdc.cancer.gov/files/37db363b-d837-4e45-ba2a-ecbbc0f85d0e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 3,335; copy number 2: 55,245; copy number 3: 289; copy number 4: 13; copy number 5: 2; copy number 6: 2; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,449,689–1,470,163, 1 gene: ATAD3C.
- chr7:57,177,409–57,180,052, 1 gene: GUSBP10.
- chr16:1,260,952–1,263,845, 1 gene: PRSS29P.
- chr19:637,105–637,537, 1 gene: AC004449.1.
- chr19:22,601,485–22,601,707, 1 gene (within-gene range 0–2): RN7SL860P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:56,477,588–56,484,386, 1 gene, copy number 6: AC092447.4.
- chr7:57,227,001–57,227,066, 1 gene, copy number 6: RNU7-157P.
- chr19:825,097–832,018, 1 gene, copy number 7: AZU1.
- chr19:22,615,552–22,623,971, 2 genes, copy number 5: LINC01785, AC011467.2.

Autosomal genes at a single copy (total copy number 1): 479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
